Somatic mutation profile of tumor specimen TCGA-BA-5151-01A (aliquot TCGA-BA-5151-01A-01D-1434-08) from TCGA case TCGA-BA-5151, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cheek mucosa; AJCC pathologic stage: Stage IVA; Tumor grade: G1; Age at diagnosis: 72.7 years (26,569 days).
Specimen TCGA-BA-5151-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d1bf0bfb-04ae-4833-87fe-94c4ce4720a7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BA-5151-10A (Blood Derived Normal), aliquot TCGA-BA-5151-10A-01D-1434-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7129ea94-e127-4bcf-8aef-399b5803782a

The open-access MAF lists 90 somatic variants for this specimen: 63 protein-altering or splice-affecting, 21 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 52, Silent 21, Nonsense Mutation 7, Intron 3, Frame Shift Ins 2, Frame Shift Del 1, Splice Site 1, RNA 1, 3'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MAP2K1 | c.171G>T p.K57N | Missense Mutation (SNP) | VAF 51/353 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs869025608, COSV61068581, COSV61070413; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- STAT3 | c.1982A>T p.D661V | Missense Mutation (SNP) | VAF 66/306 reads (22%) | hotspot (GDC flag); SIFT tolerated (0.43); PolyPhen probably damaging (0.998); catalogued as COSV52886283; called by muse, mutect2, varscan2
- TP53 | c.427G>A p.V143M | Missense Mutation (SNP) | VAF 30/81 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs587782620, CM132087, COSV52665025, COSV53025766, COSV53135444, COSV53176166; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABCC12 | c.1844G>A p.R615H | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs547878738, COSV60911544, COSV60913298; called by muse, mutect2, varscan2
- ANKRD12 | c.284C>G p.S95C | Missense Mutation (SNP) | VAF 47/188 reads (25%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.818); catalogued as COSV100041897; called by muse, mutect2, varscan2
- ARHGAP31 | c.196C>T p.R66W | Missense Mutation (SNP) | VAF 19/124 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs748347343, COSV51798990; called by muse, mutect2, varscan2
- ARID5B | c.3008C>T p.P1003L | Missense Mutation (SNP) | VAF 43/268 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.206); catalogued as rs1367766830, COSV54417539, COSV54427408; called by muse, mutect2, varscan2
- BRINP3 | c.185A>C p.D62A | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.184); catalogued as COSV100819222; called by muse, mutect2, varscan2
- BTBD3 | c.543C>G p.I181M | Missense Mutation (SNP) | VAF 29/179 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.01); catalogued as COSV99656061; called by muse, mutect2, varscan2
- CCDC180 | c.418G>A p.A140T | Missense Mutation (SNP) | VAF 19/172 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.029); catalogued as rs765085558, COSV63828913; called by muse, mutect2, varscan2
- CDC123 | c.410C>T p.S137F | Missense Mutation (SNP) | VAF 18/178 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99827136; called by muse, mutect2
- CHRD | c.1440+2T>C p.X480_splice | Splice Site (SNP) | VAF 11/114 reads (10%) | catalogued as COSV99200687; called by muse, mutect2, varscan2
- CPN2 | c.481C>G p.P161A | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.696); catalogued as COSV100103234; called by muse, mutect2, varscan2
- CR1 | c.1016G>A p.R339H (on ENST00000367051; = p.R789H on NM_000651.6) | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT tolerated (0.84); PolyPhen benign (0.031); catalogued as rs766277020, COSV100887969; called by mutect2, varscan2
- CRYZ | c.724C>T p.R242* | Nonsense Mutation (SNP) | VAF 37/193 reads (19%) | catalogued as rs756850761, COSV100558473; called by muse, mutect2, varscan2
- CTNNA2 | c.701C>T p.A234V | Missense Mutation (SNP) | VAF 43/131 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.072); catalogued as COSV100785568; called by muse, mutect2, varscan2
- DST | c.4175C>A p.S1392* (on ENST00000361203 / NM_001374722.1; = p.S1066* on NM_001723.6) | Nonsense Mutation (SNP) | VAF 65/364 reads (18%) | catalogued as COSV99758972; called by muse, mutect2, varscan2
- FAIM | c.419C>A p.T140N | Missense Mutation (SNP) | VAF 76/215 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.796); catalogued as COSV100623994; called by muse, mutect2, varscan2
- FAM83H | c.836C>T p.A279V | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66354733; called by muse, mutect2
- FHOD1 | c.407G>A p.R136H | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs754648916, COSV99264418; called by muse, mutect2, varscan2
- GADD45G | c.431A>C p.E144A | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99378653; called by muse, mutect2
- GCC1 | c.2156A>G p.N719S | Missense Mutation (SNP) | VAF 48/246 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100365619; called by muse, mutect2, varscan2
- GPLD1 | c.2138G>A p.R713H | Missense Mutation (SNP) | VAF 27/157 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57756699; called by muse, mutect2, varscan2
- HAVCR1 | c.1076G>A p.S359N | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100207897; called by muse, varscan2
- HMX3 | c.770G>A p.R257Q | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100774164; called by muse, mutect2, varscan2
- HRNR | c.2881G>A p.G961S | Missense Mutation (SNP) | VAF 109/541 reads (20%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.601); catalogued as rs1303172060, COSV100913817; called by muse, mutect2, varscan2
- ITGB3 | c.1084G>T p.D362Y | Missense Mutation (SNP) | VAF 55/302 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV101457655; called by muse, mutect2, varscan2
- ITPRID2 | c.1253A>G p.D418G | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV100238628; called by muse, mutect2, varscan2
- KIAA1210 | c.4874A>G p.Q1625R | Missense Mutation (SNP) | VAF 34/101 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.891); catalogued as COSV101274356; called by muse, mutect2, varscan2
- KIF5A | c.1832T>C p.L611P | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0.222); catalogued as COSV99673401; called by muse, mutect2, varscan2
- KNTC1 | c.6139G>A p.A2047T | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.454); catalogued as rs1201652948, COSV61083508; called by muse, mutect2, varscan2
- KRTAP10-4 | c.88G>A p.D30N | Missense Mutation (SNP) | VAF 33/200 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.673); catalogued as rs1201178194, COSV100555018; called by muse, mutect2, varscan2
- LRP4 | c.2656C>T p.R886* | Nonsense Mutation (SNP) | VAF 29/126 reads (23%) | catalogued as COSV101066802; called by muse, mutect2, varscan2
- MARCHF7 | c.43C>T p.Q15* | Nonsense Mutation (SNP) | VAF 37/114 reads (32%) | catalogued as COSV99374019; called by muse, mutect2, varscan2
- MAS1L | c.235G>T p.A79S | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT tolerated (0.36); PolyPhen benign (0.035); catalogued as COSV101009714; called by muse, mutect2, varscan2
- MUC16 | c.2939C>T p.S980L | Missense Mutation (SNP) | VAF 96/469 reads (20%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.038); catalogued as COSV67490144; called by muse, mutect2, varscan2
- MYPN | c.2764C>T p.R922C | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs759367436, COSV100590429; called by muse, mutect2, varscan2
- NLRP12 | c.263G>C p.R88T | Missense Mutation (SNP) | VAF 72/325 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as rs1206814114, COSV100145689; called by muse, mutect2, varscan2
- PCDHGB2 | c.1645C>T p.R549C | Missense Mutation (SNP) | VAF 22/131 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.219); catalogued as COSV53956288; called by muse, mutect2, varscan2
- PLIN1 | c.482C>T p.A161V | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.14); catalogued as rs766079895, COSV55582992; called by muse, mutect2, varscan2
- PLXNA1 | c.1160G>A p.W387* | Nonsense Mutation (SNP) | VAF 42/172 reads (24%) | catalogued as COSV99303908; called by muse, mutect2
- PPFIBP2 | c.1825A>T p.R609W | Missense Mutation (SNP) | VAF 63/327 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100206846; called by muse, mutect2, varscan2
- PTPRT | c.3079C>T p.R1027C | Missense Mutation (SNP) | VAF 34/181 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369430281, COSV61993792; called by muse, mutect2, varscan2
- RAB2B | c.319C>T p.H107Y | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.58); PolyPhen benign (0.066); catalogued as COSV101176855; called by muse, mutect2, varscan2
- RASGRP1 | c.554A>G p.Q185R | Missense Mutation (SNP) | VAF 22/144 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.677); catalogued as COSV100172207; called by muse, mutect2, varscan2
- RCBTB2 | c.1090G>A p.A364T | Missense Mutation (SNP) | VAF 31/172 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.217); catalogued as rs771974782, COSV60650035, COSV60650255, COSV60651745; called by muse, mutect2, varscan2
- RFLNA | c.555C>A p.C185* (on ENST00000546355 / NM_001365156.1; = p.C104* on NM_181709.4) | Nonsense Mutation (SNP) | VAF 11/63 reads (17%) | catalogued as COSV100133410; called by muse, mutect2, varscan2
- RIMS2 | c.2590C>A p.H864N (on ENST00000666250 / NM_001348490.2; = p.H672N on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/165 reads (16%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.746); catalogued as COSV99191283; called by muse, mutect2, varscan2
- RNF44 | c.482C>G p.T161S | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV99221982; called by muse, mutect2, varscan2
- RPL26L1 | c.111G>C p.E37D | Missense Mutation (SNP) | VAF 42/242 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.071); catalogued as COSV99442606; called by muse, mutect2, varscan2
- RYR1 | c.995G>A p.G332D | Missense Mutation (SNP) | VAF 44/226 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1413069646, COSV62112775; called by muse, mutect2, varscan2
- SCFD1 | c.204G>A p.M68I | Missense Mutation (SNP) | VAF 32/186 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.193); catalogued as COSV100356510; called by muse, mutect2, varscan2
- SMARCA4 | c.2738C>T p.P913L | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs778175819, COSV60785488, COSV60786996; called by muse, mutect2, varscan2
- SNX7 | c.763A>G p.N255D | Missense Mutation (SNP) | VAF 23/142 reads (16%) | SIFT tolerated (0.91); PolyPhen benign (0.003); catalogued as COSV100069351; called by muse, mutect2, varscan2
- TAOK2 | c.578T>G p.V193G | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99665248; called by muse, varscan2
- TNFRSF25 | c.1054C>T p.R352C | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1260313277, COSV100557072; called by muse, mutect2, varscan2
- USP17L2 | c.224C>T p.P75L | Missense Mutation (SNP) | VAF 22/436 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0.04); catalogued as rs1416115357, COSV61556042; called by muse, mutect2
- VPS13C | c.1250C>T p.T417I (on ENST00000644861 / NM_020821.3; = p.T374I on NM_017684.5) | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.205); catalogued as COSV99829757; called by muse, mutect2, varscan2
- ZCCHC24 | c.493C>T p.R165C | Missense Mutation (SNP) | VAF 43/236 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs770473495, COSV64886766; called by muse, mutect2, varscan2
- ZNF518A | c.1582G>T p.E528* | Nonsense Mutation (SNP) | VAF 37/276 reads (13%) | catalogued as COSV100283653; called by muse, mutect2, varscan2
- CASP8 | c.940_952delinsCTC p.I314Lfs*20 (on ENST00000432109 / NM_033355.3; = p.I331Lfs*20 on NM_001228.4) | Frame Shift Del (DEL) | VAF 69/251 reads (27%) | called by pindel, varscan2*
- CTCF | c.511dup p.A171Gfs*20 | Frame Shift Ins (INS) | VAF 19/137 reads (14%) | called by mutect2, pindel, varscan2
- FLT4 | c.3410dup p.E1138Gfs*76 | Frame Shift Ins (INS) | VAF 31/217 reads (14%) | called by mutect2, pindel, varscan2
- ARID1B | c.5766G>A p.A1922= | Silent (SNP) | VAF 52/249 reads (21%) | catalogued as rs372334858, COSV99271177; called by muse, mutect2, varscan2
- CACNA1S | c.4926C>A p.V1642= | Silent (SNP) | VAF 35/148 reads (24%) | catalogued as COSV100755262; called by muse, mutect2, varscan2
- CLDN17 | c.279C>T p.I93= | Silent (SNP) | VAF 35/155 reads (23%) | catalogued as rs138854149; called by muse, mutect2, varscan2
- CTNNA2 | c.1080T>C p.D360= | Silent (SNP) | VAF 75/214 reads (35%) | catalogued as COSV100561752; called by muse, mutect2, varscan2
- ELP4 | c.1122A>G p.L374= (on ENST00000350638; = p.L373= on NM_019040.5) | Silent (SNP) | VAF 18/91 reads (20%) | catalogued as COSV100635815; called by muse, mutect2, varscan2
- ENKD1 | c.183C>T p.P61= | Silent (SNP) | VAF 33/155 reads (21%) | catalogued as rs771769350, COSV99538936, COSV99538960; called by muse, mutect2, varscan2
- ENPEP | c.1080G>A p.E360= | Silent (SNP) | VAF 28/172 reads (16%) | catalogued as COSV99488018; called by muse, mutect2, varscan2
- GABRG2 | c.465C>T p.S155= | Silent (SNP) | VAF 39/213 reads (18%) | catalogued as COSV100729795; called by muse, mutect2, varscan2
- ITGAL | c.1845G>A p.V615= | Silent (SNP) | VAF 12/68 reads (18%) | catalogued as rs767159439, COSV100776326; called by muse, mutect2, varscan2
- MUC17 | c.13116G>A p.T4372= | Silent (SNP) | VAF 22/145 reads (15%) | catalogued as rs146965923; called by muse, mutect2, varscan2
- NCBP1 | c.1626G>A p.L542= | Silent (SNP) | VAF 13/115 reads (11%) | catalogued as COSV100910648; called by muse, mutect2, varscan2
- OR4F15 | c.433T>C p.L145= | Silent (SNP) | VAF 52/327 reads (16%) | catalogued as COSV100173936; called by muse, mutect2, varscan2
- POGLUT3 | c.1128C>A p.T376= | Silent (SNP) | VAF 18/110 reads (16%) | catalogued as COSV100052754, COSV60212066; called by muse, mutect2, varscan2
- PRDM1 | c.682C>T p.L228= | Silent (SNP) | VAF 72/422 reads (17%) | catalogued as rs186696135, COSV100958954; called by muse, mutect2, varscan2
- SESTD1 | c.1749G>T p.L583= | Silent (SNP) | VAF 21/88 reads (24%) | catalogued as COSV100090784; called by muse, mutect2, varscan2
- STAC2 | c.1167C>T p.D389= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as rs147042988; called by muse, varscan2
- TTC7B | c.1026C>T p.D342= | Silent (SNP) | VAF 18/124 reads (15%) | catalogued as rs149388931; called by muse, mutect2, varscan2
- TTI1 | c.2649G>A p.L883= | Silent (SNP) | VAF 29/155 reads (19%) | catalogued as COSV100989730; called by muse, mutect2, varscan2
- UNC80 | c.564C>T p.F188= | Silent (SNP) | VAF 77/220 reads (35%) | catalogued as rs755184462, COSV99777986; called by muse, mutect2, varscan2
- XRN1 | c.2685C>T p.P895= | Silent (SNP) | VAF 21/107 reads (20%) | catalogued as rs762389193, COSV99378716; called by muse, mutect2, varscan2
- ZNF610 | c.123G>C p.L41= | Silent (SNP) | VAF 33/182 reads (18%) | catalogued as COSV58346874; called by muse, mutect2, varscan2
- CR1 | c.487+12330G>A | Intron (SNP) | VAF 20/130 reads (15%) | catalogued as COSV100887968; called by muse, mutect2, varscan2
- NRG1 | c.1269-440T>A | Intron (SNP) | VAF 45/293 reads (15%) | catalogued as COSV99829205; called by muse, mutect2, varscan2
- RPP38 | chr10:15096711 C>T | 5'Flank (SNP) | VAF 36/313 reads (12%) | called by muse, mutect2, varscan2
- SSPOP | n.10434C>T | RNA (SNP) | VAF 13/53 reads (25%) | catalogued as COSV100947898; called by muse, mutect2, varscan2
- TMPRSS11F | c.1015+1585G>T | Intron (SNP) | VAF 35/164 reads (21%) | catalogued as COSV100678737; called by muse, mutect2, varscan2
- TRIM14 | c.*196C>T | 3'UTR (SNP) | VAF 80/408 reads (20%) | catalogued as COSV52963260, COSV99271459; called by muse, varscan2
